Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3860, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3860-01A (Primary Tumor).

Diagnosis:

This is an invasive, poorly differentiated colon carcinoma (sigmoid colon carcinoma) G3 with penetration of all parietal layers (pT3) and vascular infiltration (L1, V1),

- with regard to the resection margins in the mucosa region and in the deep circumferential resection margin, these are free resection margins,

Tumor classification:

ICDO-DA M8140/3,

G3

pT3 L1, V1, pN1 (2 of 13 + 1), locally R0

Source: NCI Genomic Data Commons file 6697411a-771d-4f10-be63-494f555158c3 (TCGA-AA-3860.6927C8E2-ACFB-4ACE-A996-636536218B52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).